Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8285, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8285-01A (Primary Tumor).

[page 1 of 3]
[Redacted]

[Redacted] Case ID	Gross Description	Microscopic Description	Diagnosis Details
[Redacted]			

[page 2 of 3]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Fundus Tumor size: 12 x 15 x 2.5 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma, intestinal type Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Lesser omentum Lymph nodes: 16/16 positive for metastasis (Intraabdominal 16/16) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 3]
Excision date

Source: NCI Genomic Data Commons file 11bae2ac-f1ea-4e94-ab39-36424ee7498c (TCGA-BR-8285.16C6D9F7-B794-4B46-99BE-FAFBE259FA1B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).